Somatic mutation profile of tumor specimen ALCH-ADC7-TTP1-A (aliquot ALCH-ADC7-TTP1-A-1-0-D-A517-36) from ALCHEMIST case ALCH-ADC7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 59.7 years (21,790 days).
Specimen ALCH-ADC7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 029dd3dd-ad22-4305-acc7-3f9daf63e317.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADC7-NB1-A (Blood Derived Normal), aliquot ALCH-ADC7-NB1-A-1-0-D-A517-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe1e778d-ea21-46c7-82ff-c2afe57a8cdc

The open-access MAF lists 39 somatic variants for this specimen: 23 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 12, RNA 2, Nonsense Mutation 1, Intron 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 91/680 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AGER | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 44/371 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs971829597; called by muse, mutect2, varscan2
- COL11A1 | c.5038C>G p.L1680V | Missense Mutation (SNP) | VAF 46/964 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV100617454; called by muse, mutect2
- FAT2 | c.4727A>T p.Q1576L | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs776516892; called by muse, mutect2
- KCNA10 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 52/627 reads (8%) | catalogued as rs752413000; called by muse, mutect2
- OR6F1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs372005274, COSV57467846; called by muse, mutect2
- CACNG6 | c.463G>C p.G155R | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAPN10 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- CDKN2AIP | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CNGB1 | c.1814A>G p.K605R | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- COL26A1 | c.1081-1G>A p.X361_splice (on ENST00000313669 / NM_001278563.3; = p.X359_splice on NM_133457.4) | Splice Site (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- CTNND1 | c.601A>T p.T201S | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- DOCK2 | c.2707T>G p.F903V | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- DSTYK | c.2362C>G p.Q788E | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.017); called by muse, mutect2
- HYDIN | c.15139T>C p.Y5047H | Missense Mutation (SNP) | VAF 40/836 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- JARID2 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 32/497 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- MYH3 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 22/632 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- N4BP1 | c.1352C>G p.A451G | Missense Mutation (SNP) | VAF 22/467 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- OR10J3 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 97/629 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMC1A | c.3479C>T p.A1160V | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SUPT6H | c.2128A>C p.T710P | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.51); called by muse, mutect2
- TXNDC11 | c.220T>A p.C74S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF676 | c.194T>A p.M65K (on ENST00000650058; = p.M33K on NM_001001411.3) | Missense Mutation (SNP) | VAF 36/455 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2
- DMD | c.4284G>A p.K1428= | Silent (SNP) | VAF 66/1396 reads (5%) | catalogued as COSV63739137; called by muse, mutect2
- DNAH14 | c.6129T>C p.C2043= (on ENST00000445597; = p.C2696= on NM_001367479.1) | Silent (SNP) | VAF 30/552 reads (5%) | called by muse, mutect2
- GPR151 | c.492G>A p.V164= | Silent (SNP) | VAF 33/217 reads (15%) | called by muse, mutect2, varscan2
- IDS | c.528A>G p.G176= | Silent (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- KIAA0100 | c.600T>C p.L200= | Silent (SNP) | VAF 8/202 reads (4%) | called by muse, mutect2
- LAG3 | c.1560C>G p.P520= | Silent (SNP) | VAF 6/134 reads (4%) | catalogued as rs1428714933; called by muse, mutect2
- MDM1 | c.1857A>G p.P619= | Silent (SNP) | VAF 64/965 reads (7%) | called by muse, mutect2
- SEMA5A | c.531G>A p.G177= | Silent (SNP) | VAF 98/504 reads (19%) | catalogued as rs183868484; called by muse, mutect2, varscan2
- SLC5A7 | c.1050T>A p.S350= | Silent (SNP) | VAF 35/882 reads (4%) | called by muse, mutect2
- UTP4 | c.1785C>T p.H595= | Silent (SNP) | VAF 107/1130 reads (9%) | called by muse, mutect2
- WFS1 | c.1224C>T p.F408= | Silent (SNP) | VAF 14/209 reads (7%) | catalogued as rs761706379; called by muse, mutect2
- ZNF493 | c.1848A>G p.E616= | Silent (SNP) | VAF 28/412 reads (7%) | catalogued as rs757838834; called by muse, mutect2
- CWC27 | c.938+3277A>G | Intron (SNP) | VAF 120/843 reads (14%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.101T>C | RNA (SNP) | VAF 30/795 reads (4%) | called by muse, mutect2
- THAP10 | c.-114C>T | 5'UTR (SNP) | VAF 12/214 reads (6%) | catalogued as rs1315044889; called by muse, mutect2
- UBE2DNL | n.467G>T | RNA (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
